Gene-level copy-number profile of tumor specimen TCGA-XY-A8S2-01A from TCGA case TCGA-XY-A8S2, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 67.8 years (24,759 days).
Specimen TCGA-XY-A8S2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.ab9436fd-ab64-4e27-92bc-7ddcf35d7943.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XY-A8S2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d0a4c2a1-ee4e-4715-a935-754c5ddc03e1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 26,991; copy number 3: 27,215; copy number 4: 2,423; copy number 5: 1,625; copy number 6: 410; copy number 7: 1; copy number 8: 143; copy number 9: 865; copy number 10: 13; copy number 11: 127.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XY-A8S2-01A-11D-A434-01): tumor purity 0.73, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,148 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,145,399–33,512,743, 14 genes, copy number 8 (within-gene range 3–8): TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1.
- chr1:34,712,737–38,046,793, 105 genes, copy number 8 (broad region; genes not listed).
- chr1:38,383,838–38,396,765, 2 genes, copy number 9: AL513479.1, RNU6-753P.
- chr1:45,326,895–45,581,321, 13 genes, copy number 10: HPDL, MUTYH, AL451136.1, TOE1, TESK2, PPIAP36, CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1.
- chr1:48,050,659–54,225,464, 163 genes, copy number 8–11 (broad region; genes not listed).
- chr1:54,236,440–54,239,063, 1 gene, copy number 8: SSBP3-AS1.
- chr12:66,767–34,249,958, 850 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
